Somatic mutation profile of tumor specimen 0DQHB3 from CCDI case PBCFAI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.7 years (620 days).
Specimen 0DQHB3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6984231e-f71e-406e-a596-a6283282a9ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQHAI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9be9dbc4-924e-426f-8abf-acca26e01025

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDM6A | c.2402A>G p.N801S | Missense Mutation (SNP) | VAF 34/838 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as rs1196875808; called by muse, mutect2
- PTPN5 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 197/398 reads (49%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs746743418; called by muse, mutect2, varscan2
- RBBP4 | c.469C>T p.H157Y | Missense Mutation (SNP) | VAF 38/768 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.011); called by muse, mutect2
- GZMB | c.528C>T p.D176= | Silent (SNP) | VAF 38/600 reads (6%) | catalogued as rs780846355; called by muse, mutect2
